Surgical pathology report (de-identified scan), TCGA case TCGA-06-2570, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2570-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

TCGA-06-2570

CLINICAL HISTORY

[REDACTED] experienced recent onset seizure, and on imaging has large right temporal lobe ring enhancing tumor with central necrosis and little edema or mass effect.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain, right temporal tumor, biopsy
B: Brain tumor, excision

PATHOLOGICAL DIAGNOSIS:

A, B. Brain, right temporal, biopsy and excision:

1. Glioblastoma.
2. MIB-1 proliferation index: 65%.
- See Microscopy Description and Comment.

COMMENT

Parts A and B are portions of cerebrum diffusely and heavily infiltrated by a glial neoplastic proliferation. The neoplastic cells are naked pleomorphic nuclei that have nuclear anaplasia, frequent mitoses, and a very high proliferation index of about 65%. There is focally prominent microvascular cellular proliferation and necrosis, and areas of tumor necrosis. Focally, also, there is suggestion of an oligodendroglial component.

The morphological features are those of a glioblastoma multiforme, with perhaps an oligodendroglial component.

LOH of 1p/19q is requested and result will be reported in an addendum.

[page 2 of 4]
Interpretation

EGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[page 3 of 4]
INTRA-OPERATIVE CONSULTATION

- A. Brain, right temporal tumor, biopsy:
1. Touch prep and smears: Glioma, probably high histological grade. Touch preparation smears performed at [redacted] and results reported to the Physician of Record.
2. Frozen sections: Glioma, probably astrocytic, high histological grade.

GROSS DESCRIPTION

- A. "Right temporal tumor," received fresh, two fragments, 0.8 cm in aggregate. Semi firm, tannish grey. In total, A1 frozen tissue, A2 remainder tissue.
- B. Brain tumor, biopsy:
FIXATIVE: None. NO. PIECES: multiple fragments of brown-tan to gray, soft, possibly necrotic tissue. SIZE/VOL: 5.0 x 4.5 x 2.0 cm, in aggregate.
CASSETTES: All- 8.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The neoplasm has a heavy GFAP-positive gliofibrillary background. Over 95% of the neoplastic cells strongly over express the p53 protein. With the MIB-1 about 65% of the cells throughout the tumor are cycling. The CD163 depicts perivascular microglia only in the areas of well preserved tumor tissue, and abundant phagocytic cells in the areas of tumor necrosis. The CD34 highlights the microvasculature with frequent microvascular cellular proliferation. The neuronal markers synaptophysin and NeuN demonstrate the diffusely infiltrative character of the neoplasm.

ICD-9(s):
191.2 191.2

Histo Data

Part A: Brain, right temporal tumor, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
1 x 1		1		
CD163 Vector x 1		2		Do also EGFRvIII. Thank
you.				
CD34-DA x 1		2		

[page 4 of 4]
[REDACTED]

MGFAP-DA x 1	2
H/E x 1	2
EMT-slides x 1	2
MB1-DA x 1	2
NeuN x 1	2
P53DO7 x 1	2
Synap-DA x 1	2
Immuno lab.	

NO NEED x microdissection.

There should be blanks in

Part B: Brain tumor, excision

Taken: [REDACTED]	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
H/E x 1	1 [REDACTED]
H/E x 1	2 [REDACTED]
H/E x 1	3 [REDACTED]
H/E x 1	4 [REDACTED]
H/E x 1	5 [REDACTED]
H/E x 1	6 [REDACTED]
H/E x 1	7 [REDACTED]
H/E x 1	8 [REDACTED]

*** End of Report ***

Source: NCI Genomic Data Commons file fbb70489-ca88-4607-bc3d-a01fbd198a6e (TCGA-06-2570.E01EA83A-97EB-41BC-841A-3F45576604FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).